MMRF case MMRF_1881 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0fb528c5-2bdb-494f-9f40-5a248043cda1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.6 years (24,317 days); ISS stage: I; Days to last known disease status: 1,018 days (2.8 years); Days to last follow up: 1,018 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 196 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 249 days; Days to treatment end: 251 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 252 days; Days to treatment end: 252 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 358 days; Days to treatment end: 447 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 448 days (1.2 years); Days to treatment end: 751 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32 (ECOG 0): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 49.1 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.05 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.34 mmol/L; Albumin 35 g/L; Total Protein 10.1 g/dL; Glucose 8.7 mmol/L.
- Day 80 (ECOG 0): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.82 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.79 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 31 µmol/L; Calcium 2.14 mmol/L; Albumin 28 g/L; Total Protein 5.9 g/dL; Glucose 7.8 mmol/L.
- Day 143 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 4.4 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.45 ×10⁹/L; Absolute Neutrophil 4.21 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 43 µmol/L; Calcium 2.37 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 4.7 mmol/L.
- Day 225 (ECOG 1): M Protein 1 g/dL; Immunoglobulin G 3.43 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.28 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 48 µmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 7.7 mmol/L.
- Day 352 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 4.79 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.74 ×10⁹/L; Absolute Neutrophil 2.35 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 40 µmol/L; Calcium 2.16 mmol/L; Albumin 30 g/L; Total Protein 5.2 g/dL; Glucose 6.1 mmol/L.
- Day 414 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.14 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 44 µmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.5 mmol/L.
- Day 527 (ECOG 0): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 8.79 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.01 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.37 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6 mmol/L.
- Day 609 (ECOG 0): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 9.3 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 1.48 ×10⁹/L; Absolute Neutrophil 0.52 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 54 µmol/L; Calcium 2.27 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.7 mmol/L.
- Day 667 (ECOG 0): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 60 µmol/L; Calcium 2.36 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6 mmol/L.
- Day 760 (ECOG 1): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 0.42 ×10⁹/L; Platelets 27 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.42 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.6 mmol/L.
- Day 899 (ECOG 1): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.47 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 8 mmol/L.
- Day 1,018 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 58 µmol/L; Calcium 2.41 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 8.2 mmol/L.

Other clinical attributes
- Day -32: Weight: 86 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1881_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_1881_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
